Somatic mutation profile of tumor specimen TCGA-AP-A052-01A (aliquot TCGA-AP-A052-01A-11W-A027-09) from TCGA case TCGA-AP-A052, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 59.5 years (21,721 days).
Specimen TCGA-AP-A052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 516730f9-9edf-4ca1-b99a-91e590e1edbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A052-10A (Blood Derived Normal), aliquot TCGA-AP-A052-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccf7166b-26ff-49f6-be2f-e90384a36683

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 3, RNA 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 82/160 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 47/55 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1266-2A>C p.X422_splice (on ENST00000340800 / NM_022977.2; = p.X381_splice on NM_004458.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 78/218 reads (36%) | catalogued as COSV61614069; called by muse, mutect2, varscan2
- ANKRD11 | c.1763C>A p.S588* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as COSV56355194, COSV56359617; called by muse, mutect2, varscan2
- AOC3 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs762768941, COSV53826071; called by muse, mutect2, varscan2
- ARAP3 | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as COSV53350159; called by muse, mutect2, varscan2
- ARNT | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV62230389; called by muse, mutect2, varscan2
- BMF | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55018979; called by muse, mutect2, varscan2
- CAPN7 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as COSV53743882; called by muse, mutect2
- CHRM5 | c.1067A>G p.Y356C | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1214012533, COSV67247213; called by muse, mutect2, varscan2
- COL14A1 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV52852504; called by muse, mutect2, varscan2
- CPB1 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.988); catalogued as COSV51571812, COSV51572954; called by muse, mutect2, varscan2
- CYP27C1 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58866232; called by muse, mutect2, varscan2
- FBXL19 | c.1900C>G p.L634V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV57941914; called by muse, mutect2, varscan2
- GABRA5 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1003947252, COSV100164895; called by mutect2, varscan2
- GPLD1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57756268; called by muse, mutect2
- MS4A4A | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59700966; called by muse, mutect2, varscan2
- MSN | c.1050G>T p.R350S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs182327269, COSV64303822; called by muse, mutect2, varscan2
- NUP214 | c.4894G>A p.A1632T | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1159715933, COSV63908996; called by muse, mutect2, varscan2
- OPRPN | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as rs1396269359, COSV101271114, COSV68192806; called by muse, mutect2
- OR3A2 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 77/117 reads (66%) | catalogued as rs1261902679, COSV68695052; called by muse, mutect2, varscan2
- PSG6 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs1378717997, COSV51832396; called by muse, mutect2
- SALL3 | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs146109999; called by muse, mutect2, varscan2
- SOCS4 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV59460407; called by muse, mutect2, varscan2
- TMED8 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); catalogued as COSV53626106; called by muse, mutect2, varscan2
- TTN | c.80118A>G p.I26706M (on ENST00000591111; = p.I19282M on NM_003319.4) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | PolyPhen benign (0.046); catalogued as COSV60001037; called by muse, mutect2
- USP24 | c.5398A>T p.N1800Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV53766250; called by muse, mutect2, varscan2
- ZNF135 | c.701G>A p.R234Q (on ENST00000313434 / NM_001289401.2; = p.R246Q on NM_003436.4) | Missense Mutation (SNP) | VAF 81/109 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs202150919, COSV57881522; called by muse, mutect2, varscan2
- ZNF267 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56252239; called by muse, mutect2, varscan2
- ZNF829 | c.39-5_65del p.X13_splice | Splice Site (DEL) | VAF 140/239 reads (59%) | catalogued as COSV61741279; called by mutect2, pindel, varscan2
- AJAP1 | c.597C>A p.G199= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs374804433; called by muse, varscan2
- GABRB3 | c.456G>T p.G152= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV54660641, COSV54663781; called by muse, mutect2, varscan2
- IRAK3 | c.1302A>G p.P434= | Silent (SNP) | VAF 6/153 reads (4%) | catalogued as COSV54161127; called by muse, mutect2
- LNX2 | c.543G>A p.L181= | Silent (SNP) | VAF 12/469 reads (3%) | catalogued as COSV60335314; called by muse, mutect2
- MBTPS2 | c.1215G>A p.Q405= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV65268317; called by muse, mutect2
- PROX1 | c.1149C>T p.F383= | Silent (SNP) | VAF 120/274 reads (44%) | catalogued as COSV54775503; called by muse, mutect2, varscan2
- SYAP1 | c.336T>G p.V112= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV66467863; called by muse, mutect2, varscan2
- ZNF560 | c.723G>A p.T241= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs572421683, COSV56866666; called by muse, mutect2, varscan2
- HERC2P3 | n.1323G>A | RNA (SNP) | VAF 9/86 reads (10%) | catalogued as rs1441782635; called by muse, varscan2
- HERC2P3 | n.1322T>G | RNA (SNP) | VAF 11/92 reads (12%) | called by muse, varscan2
